Somatic mutation profile of tumor specimen TCGA-EQ-A4SO-01A (aliquot TCGA-EQ-A4SO-01A-11D-A25D-08) from TCGA case TCGA-EQ-A4SO, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 70.9 years (25,897 days).
Specimen TCGA-EQ-A4SO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e714668-088f-48da-9560-89b0854ff6a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EQ-A4SO-10A (Blood Derived Normal), aliquot TCGA-EQ-A4SO-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e59180ac-f6e4-44b2-bf40-26b159891035

The open-access MAF lists 194 somatic variants for this specimen: 154 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 37, Frame Shift Del 14, Nonsense Mutation 8, In Frame Del 6, Splice Region 3, Splice Site 3, Frame Shift Ins 2, 5'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.376); catalogued as COSV54033486, COSV54038027; called by muse, varscan2
- ADAD2 | c.1082C>T p.P361L (on ENST00000315906 / NM_001145400.2; = p.P443L on NM_139174.4) | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766729531, COSV51894364; called by muse, mutect2, varscan2
- ADAM28 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as COSV56102175; called by muse, mutect2, varscan2
- ADAMTS16 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56998594; called by muse, mutect2, varscan2
- ADAMTS2 | c.2486C>A p.S829* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- ADGRA3 | c.3452T>C p.I1151T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV51565964; called by muse, mutect2, varscan2
- ADRA1A | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 216/604 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52369701; called by muse, mutect2, varscan2
- AHCTF1 | c.6068C>G p.S2023C (on ENST00000366508; = p.S1997C on NM_015446.5) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV100403625; called by muse, mutect2
- ANK2 | c.6221G>T p.G2074V | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.656); catalogued as COSV52151008, COSV52155554, COSV52175283; called by muse, mutect2, varscan2
- AP3S1 | c.509T>G p.L170R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs1255033625, COSV57476058; called by muse, mutect2, varscan2
- APBA2 | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.124); catalogued as COSV67105240; called by muse, mutect2, varscan2
- ASAP2 | c.2189A>G p.Q730R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.104); catalogued as COSV55635352; called by muse, mutect2, varscan2
- BIRC6 | c.9404C>G p.S3135C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs367580642; called by muse, mutect2, varscan2
- BRD4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.053); catalogued as COSV54590237; called by muse, mutect2, varscan2
- CADM1 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV59016871; called by muse, mutect2, varscan2
- CASKIN1 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58874781; called by muse, mutect2, varscan2
- CBFB | c.283-2A>C p.X95_splice | Splice Site (SNP) | VAF 14/17 reads (82%) | catalogued as COSV51999863; called by muse, varscan2
- CCR8 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV58337622; called by muse, mutect2, varscan2
- CD40LG | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 201/261 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65698827; called by muse, mutect2, varscan2
- CDH6 | c.1051A>C p.N351H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074400; called by muse, mutect2, varscan2
- CEP250 | c.2840A>C p.Q947P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61172014; called by muse, mutect2, varscan2
- CFAP47 | c.1548C>G p.F516L | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.996); catalogued as COSV52888655, COSV52892884; called by muse, mutect2, varscan2
- CFHR2 | c.664A>T p.K222* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV66381665; called by muse, mutect2, varscan2
- CIC | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV50628317; called by muse, mutect2, varscan2
- CNR1 | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs773478911, COSV62989768; called by muse, mutect2, varscan2
- CNTNAP1 | c.3298G>C p.V1100L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.251); catalogued as COSV52852454; called by muse, mutect2, varscan2
- CNTNAP5 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV70498562; called by muse, mutect2, varscan2
- CRB1 | c.698G>T p.C233F | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66344812; called by muse, mutect2
- CRB2 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV63504392; called by muse, mutect2, varscan2
- CST9 | c.255G>A p.K85= | Splice Region (SNP) | VAF 78/203 reads (38%) | catalogued as COSV65402818; called by muse, mutect2, varscan2
- CTNNA3 | c.1089A>T p.L363F | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV65604128; called by muse, mutect2, varscan2
- CYTIP | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as rs371815413, COSV51633532; called by muse, mutect2, varscan2
- DHX36 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57674999; called by muse, mutect2, varscan2
- DLGAP4 | c.1410A>G p.V470= | Splice Region (SNP) | VAF 27/83 reads (33%) | catalogued as COSV59420657; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH7 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56775091; called by muse, mutect2, varscan2
- DUSP10 | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 188/284 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV60458574; called by muse, mutect2, varscan2
- EFEMP2 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV57260851, COSV57261611; called by muse, mutect2
- ELAVL4 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.895); catalogued as rs377132231, COSV63919560; called by muse, mutect2, varscan2
- EOLA1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as rs1557347604, COSV63734135; called by muse, mutect2, varscan2
- ESRRA | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50007016; called by muse, mutect2, varscan2
- F2 | c.778A>T p.N260Y | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61316639; called by muse, mutect2, varscan2
- FLG | c.9451G>T p.A3151S | Missense Mutation (SNP) | VAF 324/731 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100911540; called by muse, mutect2, varscan2
- FSCB | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs1484795529, COSV61218957; called by muse, mutect2, varscan2
- FUT1 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1478969940, COSV100038113; called by muse, mutect2, varscan2
- GBP5 | c.1492A>G p.K498E | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV58593661; called by muse, mutect2, varscan2
- GPR12 | c.527T>G p.V176G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV67344638; called by muse, mutect2, varscan2
- GUCY1A2 | c.1716C>A p.Y572* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV56481521, COSV56494249; called by muse, mutect2, varscan2
- GULP1 | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63070666; called by muse, mutect2
- HLX | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV65045272; called by muse, mutect2, varscan2
- HMCN1 | c.15202T>C p.Y5068H | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54919922; called by muse, mutect2, varscan2
- IQGAP1 | c.2892G>C p.E964D | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51588473; called by muse, mutect2, varscan2
- KCNB1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.459); catalogued as COSV65568965; called by muse, mutect2, varscan2
- KIAA1755 | c.3278C>G p.P1093R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as COSV54078651; called by muse, mutect2
- KIF2B | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.132); catalogued as rs745346887, COSV52128186, COSV52131021, COSV52133311; called by muse, mutect2, varscan2
- LAMA2 | c.5813C>T p.A1938V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376585927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA4 | c.1657G>C p.D553H (on ENST00000230538 / NM_001105206.3; = p.D546H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV57901477; called by muse, mutect2, varscan2
- LHFPL2 | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); catalogued as COSV66715483; called by muse, mutect2, varscan2
- LHX5 | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as COSV55663506; called by muse, mutect2, varscan2
- LRP1 | c.4623G>C p.E1541D | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.107); catalogued as COSV54518710; called by muse, mutect2, varscan2
- LRPAP1 | c.351C>G p.V117= | Splice Region (SNP) | VAF 16/64 reads (25%) | catalogued as COSV56347160; called by muse, mutect2, varscan2
- LRRC73 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52502414; called by muse, mutect2, varscan2
- LTBP4 | c.4172C>T p.P1391L (on ENST00000308370 / NM_001042544.1; = p.P1354L on NM_003573.2) | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52586166; called by muse, mutect2, varscan2
- MAP3K12 | c.381C>G p.D127E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.048); catalogued as COSV57234485; called by muse, mutect2, varscan2
- MED13 | c.4625C>G p.S1542* | Nonsense Mutation (SNP) | VAF 62/149 reads (42%) | catalogued as COSV67265420; called by muse, mutect2, varscan2
- MFSD5 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs1187145681, COSV61565850; called by muse, mutect2, varscan2
- MGAT3 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.424); catalogued as COSV57866913; called by mutect2, varscan2
- MUC16 | c.40639G>T p.V13547L | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66694692; called by muse, mutect2, varscan2
- MUC16 | c.1642C>A p.P548T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs778369508, COSV67455481, COSV67490177; called by muse, mutect2, varscan2
- MYLK | c.4825G>A p.A1609T | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100658407, COSV60615954; called by muse, mutect2, varscan2
- MYOM1 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.926); catalogued as COSV55296486; called by muse, mutect2, varscan2
- NAV3 | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57096938; called by muse, mutect2, varscan2
- NDN | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59360620; called by muse, mutect2, varscan2
- NFE2L1 | c.869dup p.A291Cfs*19 | Frame Shift Ins (INS) | VAF 42/159 reads (26%) | catalogued as COSV62583861; called by mutect2, pindel, varscan2
- NLRP13 | c.2891T>G p.L964R | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61623100; called by muse, mutect2, varscan2
- NPEPPS | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.3); catalogued as COSV59104088; called by mutect2, varscan2
- OCA2 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62352047; called by muse, varscan2
- OR13G1 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100687632, COSV62944769; called by muse, mutect2, varscan2
- OR4C15 | c.165G>A p.M55I (on ENST00000314644; = p.M1? on NM_001001920.2) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1268796611, COSV58951489, COSV58954298; called by muse, mutect2, varscan2
- OR52E8 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV66209249; called by muse, mutect2, varscan2
- OR8A1 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV52509342; called by muse, mutect2, varscan2
- OSBPL7 | c.909C>G p.F303L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.97); catalogued as COSV50111947; called by muse, mutect2, varscan2
- OXCT1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.57); catalogued as COSV52167541, COSV52174002; called by muse, mutect2, varscan2
- PDGFRB | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55807842; called by muse, mutect2, varscan2
- PIK3C2B | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 180/361 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV65813120; called by muse, mutect2, varscan2
- PKD1L1 | c.4840C>A p.P1614T | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56971888; called by muse, mutect2, varscan2
- POLD1 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70956327; called by muse, mutect2, varscan2
- PSG3 | c.1046A>C p.N349T | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV59505702; called by muse, mutect2, varscan2
- PSMA6 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV54838522; called by muse, mutect2, varscan2
- PTPDC1 | c.1696C>G p.Q566E (on ENST00000375360 / NM_177995.3; = p.Q618E on NM_152422.4) | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56624718; called by muse, mutect2, varscan2
- PYGL | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV53587281; called by muse, mutect2, varscan2
- RANBP2 | c.8963C>G p.T2988S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as COSV51704603; called by muse, mutect2, varscan2
- RAPGEF3 | c.2446C>T p.P816S (on ENST00000389212; = p.P774S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs763136670, COSV50220794; called by muse, mutect2, varscan2
- RBBP5 | c.1187C>G p.S396* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | catalogued as COSV52705798; called by muse, mutect2, varscan2
- RBPJL | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1177302797, COSV59214021; called by muse, mutect2, varscan2
- RFX1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV54331854; called by muse, mutect2, varscan2
- RLN2 | c.106G>C p.G36R | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV57731563; called by muse, mutect2, varscan2
- RNF40 | c.1552-1G>C p.X518_splice | Splice Site (SNP) | VAF 84/135 reads (62%) | catalogued as COSV61215752; called by muse, mutect2, varscan2
- RPN1 | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.207); catalogued as COSV56190881; called by muse, mutect2, varscan2
- RPS4Y2 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV56488725; called by muse, mutect2, varscan2
- RTL9 | c.2242T>A p.S748T | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV71825932; called by muse, mutect2, varscan2
- RYR2 | c.2605A>G p.T869A | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63699316; called by muse, mutect2, varscan2
- SACS | c.688T>C p.C230R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.181); catalogued as COSV66544048; called by muse, mutect2, varscan2
- SDC1 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54340793; called by muse, mutect2, varscan2
- SEC16A | c.4851G>C p.E1617D | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV51534443; called by muse, mutect2, varscan2
- SET | c.407G>C p.R136T (on ENST00000372692 / NM_001374326.1; = p.R123T on NM_003011.4) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV59003447; called by muse, mutect2, varscan2
- SIK3 | c.2070C>G p.I690M (on ENST00000445177 / NM_001366686.2; = p.I648M on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52619158; called by muse, mutect2, varscan2
- SON | c.2581A>G p.M861V | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.867); catalogued as rs142324795; called by muse, varscan2
- SRRM2 | c.1456A>G p.S486G | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV57077321; called by muse, mutect2, varscan2
- STAT4 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV61828430; called by muse, mutect2, varscan2
- TCHH | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64274978, COSV64276299; called by muse, mutect2, varscan2
- TEX15 | c.3503C>G p.S1168C (on ENST00000256246; = p.S1551C on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56349998; called by muse, mutect2, varscan2
- TFPI | c.46T>C p.C16R | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV51903547; called by muse, mutect2, varscan2
- TLR9 | c.2347G>A p.G783S | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as rs769171891, COSV62346308; called by muse, mutect2, varscan2
- TONSL | c.3908A>G p.K1303R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV52872792; called by muse, mutect2, varscan2
- TRIM23 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV51553211; called by muse, mutect2, varscan2
- TROAP | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57743760; called by muse, mutect2, varscan2
- TSHZ3 | c.620T>A p.I207N | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53676952; called by muse, mutect2, varscan2
- TTC13 | c.2256C>G p.I752M | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV64169198; called by muse, mutect2, varscan2
- UBE2S | c.152-1G>C p.X51_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV52740994; called by muse, mutect2, varscan2
- UGT2B17 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58501296; called by muse, mutect2, varscan2
- UNC79 | c.608C>A p.P203Q (on ENST00000393151 / NM_001346218.2; = p.P26Q on NM_020818.5) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56399211; called by muse, mutect2, varscan2
- UPRT | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 74/93 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64920410; called by muse, mutect2, varscan2
- VPS13C | c.9796C>T p.Q3266* (on ENST00000644861 / NM_020821.3; = p.Q3223* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV51183486; called by muse, mutect2, varscan2
- WLS | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52044221; called by muse, mutect2, varscan2
- WWC1 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54654906; called by muse, mutect2, varscan2
- WWP1 | c.1875C>A p.N625K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55361839; called by muse, mutect2, varscan2
- ZBTB16 | c.1223T>A p.V408E | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV60096619; called by muse, mutect2, varscan2
- BCO1 | c.957_971del p.V320_I324del | In Frame Del (DEL) | VAF 45/79 reads (57%) | called by mutect2, pindel, varscan2
- C8orf33 | c.283del p.A95Pfs*7 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- CASP8 | c.1410_1421del p.R471_L474del (on ENST00000432109 / NM_033355.3; = p.R488_L491del on NM_001228.4) | In Frame Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- FAM171B | c.2192_2197del p.H731_Q732del | In Frame Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- FAM181A | c.978_979del p.K327Gfs*118 | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | called by mutect2, pindel, varscan2
- FGD3 | c.432C>A p.D144E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- GAPDH | c.921_934del p.V308Lfs*3 | Frame Shift Del (DEL) | VAF 77/152 reads (51%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.1940_1955del p.Q647Pfs*12 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | called by mutect2, pindel, varscan2
- HSF1 | c.177_191del p.K59_H63del | In Frame Del (DEL) | VAF 29/196 reads (15%) | called by mutect2, pindel, varscan2
- JAK1 | c.425dup p.I143Dfs*9 | Frame Shift Ins (INS) | VAF 30/47 reads (64%) | called by mutect2, varscan2
- KIR3DL3 | c.94T>C p.S32P | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KMT2C | c.8881_8882del p.P2961Wfs*6 | Frame Shift Del (DEL) | VAF 35/51 reads (69%) | called by mutect2, pindel*, varscan2*
- LEPROTL1 | c.248_256delinsTAT p.G83_I86delinsVF | In Frame Del (DEL) | VAF 21/87 reads (24%) | called by pindel, varscan2*
- N4BP2 | c.789_792del p.N263Kfs*7 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by pindel, varscan2
- NCSTN | c.1524_1536del p.S508Rfs*15 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel, varscan2
- SIGLEC6 | c.246_259delinsATCGGC p.D82Efs*89 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by pindel, varscan2*
- SMCHD1 | c.4653_4657del p.P1552Ffs*6 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 16/594 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- SPTBN1 | c.3799del p.L1267Ffs*2 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- TRDJ1 | c.27A>C p.K9N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.67995del p.S22665Rfs*97 (on ENST00000591111; = p.S15241Rfs*97 on NM_003319.4) | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.28400_28425del p.V9467Efs*6 (on ENST00000591111; = p.V8540Efs*6 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel
- WNK3 | c.2868_2894del p.Q956_D965delinsH | In Frame Del (DEL) | VAF 32/53 reads (60%) | called by mutect2, pindel, varscan2
- WNT1 | c.139del p.T48Qfs*17 | Frame Shift Del (DEL) | VAF 46/202 reads (23%) | called by mutect2, pindel, varscan2
- ZNF148 | c.822del p.K274Nfs*12 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- ABCC10 | c.393G>C p.R131= (on ENST00000372530 / NM_001198934.2; = p.R88= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV55091211, COSV99767647; called by muse, mutect2, varscan2
- ADGRB3 | c.1632C>A p.T544= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV101000238; called by muse, mutect2, varscan2
- ARMCX6 | c.69C>T p.C23= | Silent (SNP) | VAF 51/68 reads (75%) | catalogued as rs895609079, COSV62680805; called by muse, mutect2, varscan2
- BMPER | c.1395G>C p.V465= | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as rs1371837165, COSV51825885; called by muse, mutect2, varscan2
- CASR | c.2847C>T p.T949= (on ENST00000490131; = p.T1026= on NM_000388.4) | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV56139401; called by muse, mutect2, varscan2
- COPA | c.2841A>G p.V947= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV54106152; called by muse, mutect2, varscan2
- DBX1 | c.324G>A p.L108= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV57054671; called by muse, mutect2, varscan2
- DRP2 | c.399G>T p.G133= | Silent (SNP) | VAF 63/75 reads (84%) | catalogued as COSV65811102; called by muse, mutect2, varscan2
- FAM155A | c.1302G>C p.S434= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1402165891, COSV65574237; called by muse, mutect2, varscan2
- FOXJ2 | c.1632C>T p.R544= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as COSV50820789; called by muse, mutect2, varscan2
- FOXK2 | c.1734C>T p.N578= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as rs770075489, COSV58881048; called by muse, mutect2, varscan2
- GGN | c.978C>T p.P326= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1402545497, COSV53057888; called by mutect2, varscan2
- GULP1 | c.381A>T p.V127= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV63070677; called by muse, mutect2
- HARBI1 | c.366A>G p.P122= | Silent (SNP) | VAF 133/315 reads (42%) | catalogued as COSV56320918; called by muse, mutect2, varscan2
- ITPKB | c.1092C>T p.R364= | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as rs755024612, COSV55265833; called by muse, mutect2, varscan2
- KPNB1 | c.2304C>G p.A768= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV51598743; called by muse, mutect2, varscan2
- KPRP | c.537C>T p.S179= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as COSV64222340; called by muse, mutect2, varscan2
- LRTM1 | c.747T>A p.S249= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV55560847; called by muse, mutect2, varscan2
- MYH11 | c.186G>T p.L62= | Silent (SNP) | VAF 87/229 reads (38%) | catalogued as COSV55561769; called by muse, mutect2, varscan2
- MYO10 | c.4068C>T p.I1356= | Silent (SNP) | VAF 84/263 reads (32%) | catalogued as COSV57025836; called by muse, mutect2, varscan2
- NEB | c.17448C>G p.L5816= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV51437553; called by muse, mutect2, varscan2
- OR10G9 | c.486T>A p.T162= | Silent (SNP) | VAF 153/375 reads (41%) | catalogued as COSV66686520; called by muse, mutect2, varscan2
- PHKB | c.225A>C p.T75= | Silent (SNP) | VAF 47/222 reads (21%) | catalogued as COSV54527645; called by muse, mutect2, varscan2
- RNF220 | c.243C>A p.G81= | Silent (SNP) | VAF 171/521 reads (33%) | catalogued as COSV62408068; called by muse, mutect2, varscan2
- SIAE | c.6C>G p.V2= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV55015122; called by muse, mutect2, varscan2
- SLC26A2 | c.72A>C p.P24= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV53825984; called by muse, mutect2, varscan2
- SLC4A1 | c.81C>T p.P27= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs771695604, COSV52260054; called by muse, mutect2, varscan2
- SOS1 | c.3603G>A p.R1201= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV67676523; called by muse, mutect2, varscan2
- SV2C | c.2103C>A p.I701= | Silent (SNP) | VAF 51/108 reads (47%) | catalogued as COSV59224842; called by muse, mutect2, varscan2
- TDRD6 | c.2202T>G p.T734= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV60177070; called by muse, mutect2, varscan2
- TPSD1 | c.717G>C p.V239= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV52975642, COSV52977275; called by muse, mutect2, varscan2
- TRBV24-1 | c.303C>T p.I101= | Silent (SNP) | VAF 90/119 reads (76%) | catalogued as rs574268315; called by muse, mutect2, varscan2
- TRPC4AP | c.2148G>A p.E716= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV52682326; called by muse, mutect2, varscan2
- WNT9B | c.1014C>T p.C338= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs771046022, COSV51519292; called by muse, mutect2, varscan2
- ZFP69 | c.327C>T p.Y109= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV65529308; called by muse, mutect2, varscan2
- ZNF254 | c.1425A>G p.S475= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1010416989, COSV61643791; called by muse, mutect2, varscan2
- ZNF700 | c.1488A>G p.E496= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs777747861, COSV54314202; called by muse, mutect2, varscan2
- GPR142 | chr17:74372602 G>C | 3'Flank (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- MYL6 | c.-2A>G | 5'UTR (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99255182; called by muse, mutect2, varscan2
- SNORD3D | n.215G>C | RNA (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2, varscan2
